Gene-level copy-number profile of tumor specimen C3L-05848-01 from CPTAC case C3L-05848, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 70.6 years (25,797 days).
Specimen C3L-05848-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 97af8d69-7d98-4424-8a92-14eda4f6e41d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05848-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/2806ba6d-a917-4270-9c93-5d37b07fe9ce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 13,093; copy number 2: 40,986; copy number 3: 3,665; copy number 4: 201; copy number 5: 82; copy number 6: 113; copy number 7: 76; copy number 8: 1; copy number 9: 23; copy number 10: 72; copy number 11: 7; copy number 12: 58; copy number 18: 9.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,272,393–25,330,445, 2 genes (within-gene range 0–1): RHD, SDHDP6.
- chr2:77,672,215–77,673,792, 1 gene: AC084149.1.
- chr9:12,134–73,865, 5 genes (within-gene range 0–1): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C.
- chr9:6,532,467–6,645,729, 4 genes (within-gene range 0–1): GLDC, RN7SL25P, AL353718.1, RPL23AP57.
- chr9:28,863,626–28,888,955, 2 genes: MIR876, MIR873.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 441 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,913,045–156,248,117, 23 genes, copy number 5: KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6.
- chr5:179,678,628–179,731,641, 1 gene, copy number 7 (within-gene range 2–7): CANX.
- chr5:179,732,822–180,072,113, 15 genes, copy number 7 (within-gene range 2–7): MAML1, LTC4S, MGAT4B, MIR1229, SQSTM1, MRNIP, RN7SKP150, Y_RNA, AC008393.1, TBC1D9B, RNF130, RPS15AP18, AC010285.2, AC010285.1, AC010285.3.
- chr11:63,681,446–63,970,576, 11 genes, copy number 5: RTN3, AP000753.3, C11orf95, RN7SL596P, SPINDOC, ATP5MGP1, MARK2, RNU6-1306P, RCOR2, NAA40, RNU6-45P.
- chr12:105,173,297–105,396,097, 4 genes, copy number 7: APPL2, C12orf75, AC078874.1, KCCAT198.
- chr17:74,862,497–75,405,709, 35 genes, copy number 5 (within-gene range 4–5): FDXR, FADS6, USH1G, OTOP2, OTOP3, HID1, HID1-AS1, CDR2L, MRPL58, RNU6-362P, KCTD2, ATP5PD, RN7SL573P, AC111186.1, TRIM80P, SLC16A5, Y_RNA, ARMC7, NT5C, AC022211.4, JPT1, AC022211.3, AC022211.1, Y_RNA, SUMO2, NUP85, GGA3, MRPS7, MIF4GD, AC022211.2, SLC25A19, GRB2, AC011933.1, AC011933.4, AC011933.2.
- chr17:76,309,478–76,738,522, 33 genes, copy number 5–6 (within-gene range 4–6): PRPSAP1, Y_RNA, RNU6-24P, AC090699.1, SPHK1, UBE2O, RPL7P49, AANAT, RHBDF2, CYGB, PRCD, AC015802.4, AC015802.3, AC015802.5, SNHG16, SNORD1C, SNORD1B, SNORD1A, AC015802.6, ST6GALNAC2, AC015802.1, AC015802.2, ST6GALNAC1, RNU6-227P, AC005837.1, MXRA7, RNY4P36, AC005837.4, JMJD6, AC005837.3, METTL23, AC005837.2, SRSF2.
- chr17:76,736,450–76,736,548, 1 gene, copy number 6 (within-gene range 4–6): MIR636.
- chr19:28,294,093–34,512,304, 128 genes, copy number 7–18 (broad region; genes not listed).
- chr19:39,328,353–41,307,787, 111 genes, copy number 6–10 (within-gene range 1–10) (broad region; genes not listed).
- chr19:41,449,520–42,670,816, 64 genes, copy number 6 (broad region; genes not listed).
- chr19:46,601,074–46,661,182, 6 genes, copy number 6 (within-gene range 2–6): CALM3, AC093503.1, PTGIR, GNG8, AC093503.2, DACT3.
- chr22:18,733,914–18,757,906, 1 gene, copy number 8: FAM230E.
- chr22:46,360,834–46,679,790, 4 genes, copy number 5: CELSR1, AL031597.1, AL021392.1, GRAMD4.
- chr22:46,762,617–47,261,007, 4 genes, copy number 6 (within-gene range 2–6): TBC1D22A, TBC1D22A-AS1, FP325331.1, Z83836.1.

Autosomal genes at a single copy (total copy number 1): 12,425. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
